Gene-level copy-number profile of tumor specimen TCGA-D3-A51E-06A from TCGA case TCGA-D3-A51E, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.0 years (16,788 days).
Specimen TCGA-D3-A51E-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.39b0781b-07f3-4568-9a2d-52fa94e19737.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A51E-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 832 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d4de8f8-c2ac-44db-8bee-02e56e2c4ebc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,954; copy number 2: 43,795; copy number 3: 7,137; copy number 4: 686; copy number 5: 23; copy number 6: 1,113; copy number 17: 32; copy number 18: 7; copy number 26: 6; copy number 31: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A51E-06A-11D-A25P-01): tumor purity 0.77, ploidy 2.1, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,219 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:167,607–33,339,495, 992 genes, copy number 6 (broad region; genes not listed).
- chr9:38,804,007–39,288,315, 7 genes, copy number 18 (within-gene range 1–18): AL845311.1, AL953883.1, VN2R3P, CNTNAP3, RBM17P1, AL353729.2, AL353729.1.
- chr11:66,563,464–68,449,275, 96 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:68,488,609–68,488,840, 1 gene, copy number 6: NDUFA3P2.
- chr11:69,641,156–72,005,715, 75 genes, copy number 17–31 (broad region; genes not listed).
- chr11:72,014,291–72,020,910, 1 gene, copy number 31: AP002490.1.
- chr18:657,653–1,408,344, 23 genes, copy number 6 (within-gene range 4–6): TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2.
- chr18:1,655,177–1,779,955, 1 gene, copy number 6 (within-gene range 4–6): AC019183.1.
- chr22:37,891,347–38,281,289, 23 genes, copy number 5: RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534, AL031587.1, AL031587.4, PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP.

Autosomal genes at a single copy (total copy number 1): 4,533. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
